Somatic mutation profile of tumor specimen TCGA-92-8064-01E (aliquot TCGA-92-8064-01E-01D-A38P-08) from TCGA case TCGA-92-8064, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 58.6 years (21,417 days).
Specimen TCGA-92-8064-01E: Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce942f59-9df9-4222-be9d-1e5bb0dce82e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-92-8064-10A (Blood Derived Normal), aliquot TCGA-92-8064-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c481ed59-fac9-41cd-9a9a-0415c38e4d3e

The open-access MAF lists 100 somatic variants for this specimen: 78 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 18, Frame Shift Del 5, Nonsense Mutation 4, Intron 3, Splice Site 3, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 16/121 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519924, COSV67962147; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 16/118 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960135, COSV67960407, COSV67962953; called by muse, mutect2, varscan2
- BRCA2 | c.7507G>C p.V2503L | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV66451402, COSV66463407; called by muse, mutect2, varscan2
- CCL21 | c.383C>A p.S128* | Nonsense Mutation (SNP) | VAF 7/79 reads (9%) | catalogued as rs1370944166; called by muse, mutect2
- CDH11 | c.1359G>T p.W453C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51770173, COSV51771651; called by muse, mutect2, varscan2
- CLDN16 | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs376431300, CM116890; called by muse, mutect2, varscan2
- DGAT2L6 | c.802G>T p.G268C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145712346; called by muse, mutect2, varscan2
- DLAT | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1555179651; called by muse, mutect2
- ECT2 | c.1519G>T p.D507Y (on ENST00000392692 / NM_001349098.2; = p.D476Y on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1208066079; called by muse, mutect2, varscan2
- ELAVL2 | c.496A>T p.R166W | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56356678; called by muse, mutect2, varscan2
- FLG | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV64249223; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs1345732673; called by muse, mutect2, varscan2
- ITGAX | c.2198G>T p.R733L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs761201188, COSV51643111; called by muse, mutect2, varscan2
- KDR | c.1157T>C p.M386T | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs949197675, COSV55779451; called by muse, mutect2, varscan2
- KIF21A | c.2023A>G p.K675E (on ENST00000361418 / NM_001378440.1; = p.K662E on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62774803; called by muse, mutect2
- LAMC1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99280636; called by muse, mutect2
- MYO3A | c.2596G>T p.V866L | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56333440; called by muse, mutect2, varscan2
- NEUROD4 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 47/414 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV54470829; called by muse, mutect2, varscan2
- NFASC | c.3221C>A p.T1074K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58361685; called by mutect2, varscan2
- NLRP9 | c.1382G>C p.R461P | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as rs758078069, COSV100242391, COSV100242973; called by mutect2, varscan2
- OR4K13 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as rs756620210, COSV59860515; called by muse, mutect2, varscan2
- OR5B17 | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV62160625; called by muse, mutect2
- OR6N1 | c.111G>C p.M37I | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58647755, COSV58650332; called by muse, mutect2
- PAPPA2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs375011994, COSV62779185; called by muse, mutect2, varscan2
- PAQR3 | c.811G>T p.G271* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as rs754070447; called by mutect2, varscan2
- SERINC2 | c.810G>T p.Q270H (on ENST00000373709 / NM_178865.5; = p.Q274H on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101036882; called by muse, mutect2
- TAF1L | c.1327A>G p.K443E | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as rs1367392431; called by muse, mutect2, varscan2
- TMEM64 | c.796-1G>T p.X266_splice | Splice Site (SNP) | VAF 7/49 reads (14%) | catalogued as COSV101375986; called by muse, mutect2, varscan2
- TNKS | c.3805G>T p.A1269S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60067648; called by muse, mutect2, varscan2
- TRIM48 | c.579-1G>T p.X193_splice | Splice Site (SNP) | VAF 12/57 reads (21%) | catalogued as rs750079377, COSV101338176; called by muse, mutect2, varscan2
- ZNF711 | c.623-1G>T p.X208_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99340617; called by muse, mutect2, varscan2
- ADHFE1 | c.1030A>T p.K344* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- AIM2 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.03); called by muse, mutect2
- ATP13A5 | c.3079A>T p.N1027Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ATP6V0A1 | c.2500A>T p.K834* (on ENST00000343619 / NM_001378531.1; = p.K828* on NM_005177.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- BICRAL | c.2603G>C p.G868A | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BRINP2 | c.1967G>C p.S656T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CD164L2 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CD36 | c.885_886del p.P296Ifs*9 | Frame Shift Del (DEL) | VAF 18/189 reads (10%) | called by mutect2, pindel
- CDH9 | c.1254G>C p.K418N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2
- CNR1 | c.1291T>A p.C431S | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CST11 | c.301A>T p.N101Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DGKB | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- DMRTB1 | c.1023_1024del p.D342Lfs*30 | Frame Shift Del (DEL) | VAF 13/123 reads (11%) | called by mutect2, pindel, varscan2
- ELAVL4 | c.237A>T p.R79S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2
- EPDR1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- FBXO31 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRMD3 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2
- GDF5 | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GPAM | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HRNR | c.3280_3281del p.A1094* | Frame Shift Del (DEL) | VAF 24/184 reads (13%) | called by mutect2, varscan2
- ITGAX | c.1384C>T p.L462F | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNQ3 | c.2463T>G p.N821K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by mutect2, varscan2
- LCT | c.3691G>C p.E1231Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LCT | c.1345_1369del p.Q449Gfs*24 | Frame Shift Del (DEL) | VAF 3/41 reads (7%) | called by mutect2, pindel
- MAN2B2 | c.1520G>C p.G507A | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- MIPOL1 | c.773T>A p.I258K | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTERF4 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NEB | c.4220A>T p.Q1407L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NOVA1 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NR3C2 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2
- OR10K1 | c.529T>A p.F177I | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- PKP2 | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- RC3H1 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEL1L2 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SERINC2 | c.811G>T p.A271S (on ENST00000373709 / NM_178865.5; = p.A275S on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.934); called by muse, mutect2
- SGCA | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- SLC15A2 | c.37_38del p.L13Ffs*7 | Frame Shift Del (DEL) | VAF 40/207 reads (19%) | called by pindel, varscan2
- SLC25A5 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SPTA1 | c.7091dup p.A2365Gfs*44 | Frame Shift Ins (INS) | VAF 10/72 reads (14%) | called by mutect2, varscan2
- SYNE1 | c.13961T>G p.V4654G (on ENST00000367255 / NM_182961.4; = p.V4583G on NM_033071.3) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TAF1L | c.2309C>A p.P770Q | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- THAP6 | c.14G>T p.C5F | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAV10 | c.164G>C p.R55T | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- TRIM47 | c.1300A>T p.S434C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- WDR17 | c.2024C>A p.S675Y | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBBX | c.7A>G p.R3G | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF624 | c.563A>G p.Q188R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.346); called by muse, mutect2
- ABCC8 | c.1197T>A p.I399= | Silent (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- CCDC171 | c.942T>A p.A314= | Silent (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2, varscan2
- DNAH5 | c.3141G>A p.G1047= | Silent (SNP) | VAF 13/106 reads (12%) | called by muse, mutect2, varscan2
- DSCAM | c.3150C>T p.T1050= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1418597590; called by muse, mutect2, varscan2
- F5 | c.1794T>A p.T598= | Silent (SNP) | VAF 4/43 reads (9%) | called by mutect2, varscan2
- F5 | c.600G>A p.E200= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV100889203; called by muse, mutect2, varscan2
- NAPRT | c.1242G>A p.K414= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- OR11H1 | c.925C>T p.L309= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as COSV99079129; called by mutect2, varscan2
- OR52A5 | c.255C>A p.G85= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.1008A>T p.T336= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- PCNX2 | c.3405C>T p.A1135= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs753050544, COSV50780698, COSV50789089; called by mutect2, varscan2
- POLR3F | c.816A>T p.A272= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as rs1470434304; called by muse, mutect2
- PTPRD | c.4644G>T p.P1548= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- SLC8A2 | c.285G>T p.A95= | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- SUPT6H | c.4776C>T p.G1592= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs771684139; called by mutect2, varscan2
- SYT7 | c.879C>T p.L293= | Silent (SNP) | VAF 23/451 reads (5%) | called by muse, mutect2
- TEP1 | c.4068G>A p.K1356= | Silent (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- TMEM64 | c.1039C>T p.L347= | Silent (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845966 G>A | 5'Flank (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- CCDC34 | c.606+64A>G | Intron (SNP) | VAF 6/56 reads (11%) | catalogued as rs1199563995; called by mutect2, varscan2
- GNAO1 | c.723+6943C>A | Intron (SNP) | VAF 5/32 reads (16%) | catalogued as rs1443040664; called by muse, mutect2
- IQCJ-SCHIP1 | c.291+11153C>A | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as COSV61841911; called by mutect2, varscan2
